Gene-level copy-number profile of tumor specimen MP2PRT-PARDMN-TTP1-A from MP2PRT case MP2PRT-PARDMN, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.1 years (1,881 days).
Specimen MP2PRT-PARDMN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69aef0e3-ef6f-41bb-a9f0-6230f26bd257.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARDMN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/07fad795-f786-4553-9554-cc2d9c8f172d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 7,814; copy number 2: 48,003; copy number 3: 3,072.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:587,629–686,673, 10 genes (within-gene range 0–2): AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr16:70,114,332–70,173,483, 2 genes (within-gene range 0–1): PDPR, AC009060.1.
- chr16:74,367,462–74,441,937, 5 genes (within-gene range 0–1): AC009053.2, NPIPB15, AC009053.4, CLEC18B, AC009053.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,958. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
